Somatic mutation profile of tumor specimen MMRF_1714_1_BM_CD138pos (aliquot MMRF_1714_1_BM_CD138pos_T1_KBS5U_L04785) from MMRF case MMRF_1714, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.4 years (19,157 days).
Specimen MMRF_1714_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 075d2540-f1c3-4783-af27-0ec1753e3da0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1714_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1714_1_PB_Whole_C3_KBS5U_L04798; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbce2c01-f22e-414f-a624-16884d9b4571

The open-access MAF lists 79 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, 3'UTR 21, Silent 10, Intron 6, Nonsense Mutation 4, Splice Site 3, RNA 3, 3'Flank 1, 5'Flank 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 89/210 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.16286C>T p.P5429L | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.375); catalogued as rs752919542; called by muse, mutect2, varscan2
- CACNA1S | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as rs553739117, COSV100755051; called by muse, mutect2, varscan2
- CALHM4 | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 87/193 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs774810184; called by muse, mutect2, varscan2
- ELN | c.2032G>A p.A678T (on ENST00000320399 / NM_001278939.1; = p.A645T on NM_000501.4) | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.15); catalogued as rs782348158, CD113776; called by muse, mutect2, varscan2
- IGHV1-69D | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 60/104 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1457115666; called by muse, varscan2
- IGHV4-34 | c.236A>G p.H79R | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1064185; called by muse, varscan2
- NCAM2 | c.2457A>G p.I819M | Missense Mutation (SNP) | VAF 71/144 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs1342189207; called by muse, mutect2, varscan2
- NUMA1 | c.5960G>A p.R1987H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs374984536; called by muse, mutect2
- NWD2 | c.1885G>A p.V629I | Missense Mutation (SNP) | VAF 62/118 reads (53%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.959); catalogued as rs754793058; called by muse, mutect2, varscan2
- OR8K3 | c.661A>T p.I221F | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.451); catalogued as rs1565108689; called by muse, mutect2
- PLEC | c.11318G>A p.G3773D (on ENST00000322810 / NM_201380.4; = p.G3663D on NM_000445.5) | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs782517278; called by muse, mutect2
- SLC9A3 | c.1718C>T p.T573M | Missense Mutation (SNP) | VAF 67/121 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.373); catalogued as rs148343380; called by muse, mutect2, varscan2
- SOX13 | c.1231+1G>A p.X411_splice | Splice Site (SNP) | VAF 12/40 reads (30%) | catalogued as rs1324705887; called by muse, mutect2, varscan2
- TCHH | c.3151C>T p.R1051W | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.853); catalogued as rs779106201, COSV100915018; called by muse, mutect2
- ZXDA | c.2369T>C p.I790T | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763181335, COSV62388828; called by muse, mutect2, varscan2
- ARHGAP12 | c.2195T>A p.M732K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP2B1 | c.383A>T p.Q128L | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CSMD2 | c.3968A>T p.H1323L | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- EFCAB6 | c.3830T>A p.L1277* | Nonsense Mutation (SNP) | VAF 17/59 reads (29%) | called by muse, mutect2, varscan2
- EGR1 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 63/105 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- GFM2 | c.896T>G p.F299C | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); called by muse, mutect2
- H2AC20 | c.326T>A p.L109* | Nonsense Mutation (SNP) | VAF 11/158 reads (7%) | called by muse, mutect2
- HFM1 | c.3668+2T>A p.X1223_splice | Splice Site (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- IGHD2-21 | c.8T>A p.L3* | Nonsense Mutation (SNP) | VAF 25/27 reads (93%) | called by muse, varscan2
- IGHG1 | c.310_314del p.D104Nfs*11 | Frame Shift Del (DEL) | VAF 21/35 reads (60%) | called by mutect2, pindel, varscan2
- IGKV4-1 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAG | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 22/98 reads (22%) | called by muse, mutect2, varscan2
- MARF1 | c.1997A>C p.E666A | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.45); called by muse, mutect2
- OTOGL | c.2167T>C p.Y723H (on ENST00000547103; = p.Y714H on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT tolerated (0.76); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- POLR1C | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2
- RECQL5 | c.1670T>A p.L557Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RPUSD1 | c.254G>A p.S85N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SF3B3 | c.2918G>C p.G973A | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SQOR | c.865-1G>C p.X289_splice | Splice Site (SNP) | VAF 22/75 reads (29%) | called by muse, mutect2, varscan2
- TNFAIP3 | c.1571G>A p.C524Y | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ABCA13 | c.14925T>C p.F4975= | Silent (SNP) | VAF 130/196 reads (66%) | called by muse, mutect2, varscan2
- ARMC2 | c.2172G>A p.A724= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs762725128, COSV64550845; called by mutect2, varscan2
- CATSPERB | c.3117A>G p.L1039= | Silent (SNP) | VAF 119/222 reads (54%) | called by muse, mutect2, varscan2
- FAT1 | c.12774G>A p.P4258= | Silent (SNP) | VAF 66/143 reads (46%) | catalogued as rs370465267, COSV71676234; called by muse, mutect2, varscan2
- IGHD2-21 | c.7T>C p.L3= | Silent (SNP) | VAF 26/28 reads (93%) | catalogued as rs781854746; called by muse, varscan2
- IGKV1-8 | c.150C>T p.S50= | Silent (SNP) | VAF 56/131 reads (43%) | catalogued as rs577716550; called by muse, mutect2, varscan2
- KRT12 | c.1227C>T p.N409= | Silent (SNP) | VAF 5/70 reads (7%) | catalogued as rs761216031; called by muse, mutect2
- MYO18B | c.4131C>T p.L1377= | Silent (SNP) | VAF 33/70 reads (47%) | catalogued as rs751460528; called by muse, mutect2, varscan2
- SEMA4B | c.1191A>G p.G397= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- ZSCAN18 | c.93G>A p.Q31= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as rs1039071673; called by muse, mutect2, varscan2
- AC097518.1 | n.290C>T | RNA (SNP) | VAF 120/255 reads (47%) | called by muse, mutect2
- ADAMTS19 | c.*405T>G | 3'UTR (SNP) | VAF 69/120 reads (58%) | called by muse, mutect2, varscan2
- AGR2 | c.*390C>T | 3'UTR (SNP) | VAF 52/172 reads (30%) | called by muse, mutect2, varscan2
- AQP6 | c.403-280C>T | Intron (SNP) | VAF 131/280 reads (47%) | called by muse, mutect2, varscan2
- BMP6 | c.*1086_*1109del | 3'UTR (DEL) | VAF 22/74 reads (30%) | called by mutect2, pindel, varscan2
- BMPR1B | chr4:95156772 T>G | 3'Flank (SNP) | VAF 43/95 reads (45%) | called by muse, mutect2, varscan2
- CA5B | c.*4380C>T | 3'UTR (SNP) | VAF 26/32 reads (81%) | called by muse, mutect2, varscan2
- CADPS | c.1325+19810A>T | Intron (SNP) | VAF 30/108 reads (28%) | called by muse, mutect2, varscan2
- CHD5 | c.*241C>A | 3'UTR (SNP) | VAF 40/73 reads (55%) | called by muse, mutect2, varscan2
- CKMT1A | c.*133A>T | 3'UTR (SNP) | VAF 21/400 reads (5%) | called by muse, mutect2
- COPS3 | c.*390T>C | 3'UTR (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- CPNE4 | c.*494_*496del | 3'UTR (DEL) | VAF 33/93 reads (35%) | called by pindel, varscan2
- DCLK3 | c.*2697G>A | 3'UTR (SNP) | VAF 78/315 reads (25%) | catalogued as COSV69363469; called by muse, mutect2, varscan2
- DDX20 | c.*1073G>A | 3'UTR (SNP) | VAF 14/28 reads (50%) | catalogued as rs1391179011; called by muse, mutect2, varscan2
- EFCAB2 | c.*2962C>T | 3'UTR (SNP) | VAF 30/80 reads (38%) | catalogued as rs750585675; called by muse, mutect2
- EGFEM1P | n.866A>T | RNA (SNP) | VAF 114/177 reads (64%) | called by muse, mutect2, varscan2
- FBXW7 | chr4:152536464 G>A | 5'Flank (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- GUSBP10 | n.201A>G | RNA (SNP) | VAF 21/26 reads (81%) | catalogued as rs746816764; called by muse, mutect2, varscan2
- HSPG2 | c.3888+58G>A | Intron (SNP) | VAF 52/92 reads (57%) | catalogued as rs543973193; called by muse, mutect2, varscan2
- KATNAL1 | c.*4923C>T | 3'UTR (SNP) | VAF 18/29 reads (62%) | called by muse, mutect2, varscan2
- LIMD1 | c.*4124T>A | 3'UTR (SNP) | VAF 24/170 reads (14%) | called by muse, mutect2, varscan2
- LIMD1 | c.*7136G>A | 3'UTR (SNP) | VAF 77/128 reads (60%) | catalogued as rs967278207; called by muse, mutect2, varscan2
- LSM5 | c.243+157T>C | Intron (SNP) | VAF 69/218 reads (32%) | called by muse, mutect2, varscan2
- NDNF | c.*43A>G | 3'UTR (SNP) | VAF 41/62 reads (66%) | called by muse, mutect2, varscan2
- NEK2 | c.1111+512T>C | Intron (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- PCDHA9 | c.-56A>G | 5'UTR (SNP) | VAF 127/362 reads (35%) | called by muse, mutect2, varscan2
- PCMTD1 | c.*1770A>T | 3'UTR (SNP) | VAF 64/258 reads (25%) | called by muse, mutect2, varscan2
- SEC14L4 | c.*956C>G | 3'UTR (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- SELENOI | c.*1612C>T | 3'UTR (SNP) | VAF 46/127 reads (36%) | catalogued as rs953270310; called by muse, mutect2, varscan2
- SOX4 | c.*848G>T | 3'UTR (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
- TSC1 | c.*3705C>T | 3'UTR (SNP) | VAF 18/139 reads (13%) | called by muse, mutect2
- TTC6 | c.1201-4114C>T | Intron (SNP) | VAF 36/72 reads (50%) | catalogued as COSV57447427; called by muse, mutect2, varscan2
- ZNF148 | c.*688T>C | 3'UTR (SNP) | VAF 115/171 reads (67%) | called by muse, mutect2, varscan2
